TCGA case TCGA-DX-A3U6 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6201394f-b70e-4f14-9519-ff9d5f06eb09

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Dead; Days to death: 1,088 days (3.0 years).

Diagnoses (3)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 63.5 years (23,193 days); Year of diagnosis: 2011; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 8.5; Tumor width measurement: 7.5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 7.5; Tumor length measurement: 8.5; Tumor width measurement: 8.1.
   Pathology details: Measurement type: Pathologic; Tumor burden: 21.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2; Tumor length measurement: 4; Tumor width measurement: 3.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Tumor depth descriptor: Deep.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 63.9 years (23,353 days); Days to diagnosis: 160 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3.2; Tumor length measurement: 6.5; Tumor width measurement: 5.
3. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 64.6 years (23,599 days); Days to diagnosis: 406 days (1.1 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 160 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 160 days.
- Day 406 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 406 days (1.1 years).
- Days to follow up: 540 days (1.5 years); Disease response: With Tumor.
- Days to follow up: 1,088 days (3.0 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A3U6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 910 mg.
  Slide TCGA-DX-A3U6-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A3U6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A3U6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Margin status: Negative; Disease multifocal indicator: No; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor sizes, Tumor size 2: Lesion pathologic depth: 4.
- Primary pathology, Tumor sizes, Tumor size 3: Lesion pathologic length: 4; Lesion pathologic depth: 2.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Complete Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 484; Pharmaceutical therapy drug name: PD 0332991; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 554; Days from index date to pharmaceutical treatment ended: 966; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Partial Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,088 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,088 days; disease-free interval: event (new tumor event after initially disease-free), 160 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 160 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A3U6-01A-11D-A29M-01): tumor purity 0.2, ploidy 2.06, whole-genome doublings 0.
